Somatic mutation profile of tumor specimen TCGA-14-1034-01A (aliquot TCGA-14-1034-01A-01D-1492-08) from TCGA case TCGA-14-1034, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.3 years (22,029 days).
Specimen TCGA-14-1034-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84e9de46-0d84-4ef9-a9dd-8dfacbc92adf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1034-10A (Blood Derived Normal), aliquot TCGA-14-1034-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3d7ea4e-dd44-449a-a766-217f6fd215f3

The open-access MAF lists 79 somatic variants for this specimen: 61 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 53, Silent 18, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060501195, CM043949, COSV52726068, COSV52741717, COSV53015551; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADGRE3 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 109/415 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs192735238, COSV53729478; called by muse, mutect2, varscan2
- ADGRG4 | c.7751C>A p.S2584Y | Missense Mutation (SNP) | VAF 153/498 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV54952704; called by muse, mutect2, varscan2
- AHNAK2 | c.12121G>A p.V4041M | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.791); catalogued as rs774913744, COSV60911727, COSV60915794; called by muse, mutect2, varscan2
- APBA1 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); catalogued as rs199962660, COSV55222437; called by muse, mutect2, varscan2
- ARHGAP45 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1286260881, COSV57430607; called by muse, mutect2, varscan2
- ARSD | c.218C>G p.A73G | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54199043; called by muse, mutect2, varscan2
- AVL9 | c.1802G>C p.R601P | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59464907; called by muse, mutect2, varscan2
- B3GNT2 | c.853A>G p.K285E | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); catalogued as COSV57344289; called by muse, mutect2, varscan2
- CACNA1S | c.5371G>A p.A1791T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); catalogued as COSV62938250; called by muse, mutect2, varscan2
- CCDC22 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs199545573, COSV59903756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP206 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV51533210; called by muse, mutect2, varscan2
- CMBL | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.171); catalogued as rs762358334, COSV56983195; called by muse, mutect2, varscan2
- COL6A2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142880107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYC1 | c.697T>A p.F233I | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59644132; called by muse, mutect2, varscan2
- DCDC1 | c.2440C>A p.Q814K | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV60838549; called by muse, mutect2, varscan2
- EDARADD | c.197G>A p.R66Q (on ENST00000334232 / NM_145861.4; = p.R56Q on NM_080738.4) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1163649519, COSV62061939; called by muse, mutect2, varscan2
- EGFR | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51775191, COSV51835541; called by muse, mutect2, varscan2
- EPX | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs1386568929, COSV56595676; called by muse, mutect2, varscan2
- F13A1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as rs751922706, COSV53556332; called by muse, varscan2
- GALNT8 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.438); catalogued as rs375631897; called by muse, mutect2, varscan2
- GPR174 | c.582T>A p.F194L | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52131920; called by muse, mutect2, varscan2
- GRM8 | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs537365104, COSV58807793; called by muse, mutect2, varscan2
- H2BC1 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs1238051800, COSV51237036; called by muse, mutect2, varscan2
- HASPIN | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV53992047; called by muse, mutect2
- HCN1 | c.1795T>C p.S599P | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1382153041, COSV57501931; called by muse, mutect2, varscan2
- HYDIN | c.6166G>A p.V2056M | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs751359283, COSV99993101; called by muse, mutect2, varscan2
- KIAA1210 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.66); catalogued as COSV68176404; called by muse, mutect2, varscan2
- KRT23 | c.471del p.F157Lfs*26 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as COSV52928753; called by mutect2, pindel, varscan2
- LMO7 | c.1546C>T p.R516* (on ENST00000357063; = p.R246* on NM_015842.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/98 reads (57%) | catalogued as rs1374855264, COSV58532682; called by muse, mutect2, varscan2
- LRRC31 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 156/451 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52980193; called by muse, mutect2, varscan2
- MEAK7 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs146039021; called by muse, mutect2, varscan2
- NECAB2 | c.1078G>A p.V360I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs547664063, COSV59419969; called by muse, mutect2, varscan2
- NF1 | c.7971del p.X2657_splice (on ENST00000358273 / NM_001042492.3; = p.X2636_splice on NM_000267.3) | Splice Site (DEL) | VAF 24/59 reads (41%) | catalogued as COSV62193417, COSV62221929; called by mutect2, pindel, varscan2
- NOX4 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV54450141; called by muse, mutect2, varscan2
- OR5K4 | c.8G>T p.R3M | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV61583578; called by muse, mutect2, varscan2
- PLCG2 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369516453; called by muse, mutect2, varscan2
- PPEF1 | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs778812457, COSV62995430; called by muse, mutect2, varscan2
- PPP2R1B | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs367938997; called by muse, mutect2, varscan2
- PTEN | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CD993696, COSV64289071, COSV64293681, COSV64309763; called by muse, mutect2, varscan2
- SAFB2 | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs770444467, COSV53042986, COSV99385817; called by mutect2, varscan2
- SFTPC | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs199854076; called by muse, mutect2, varscan2
- SLC26A7 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs773402742, COSV52589677; called by muse, mutect2
- SLITRK6 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV68389785, COSV68391987; called by muse, mutect2, varscan2
- SRGAP1 | c.2167G>A p.G723S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs745328019, COSV100754839, COSV61896161; called by muse, mutect2, varscan2
- TAS2R41 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 55/191 reads (29%) | catalogued as rs376728592; called by muse, mutect2, varscan2
- TG | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55070864; called by muse, mutect2, varscan2
- TLE2 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53579078; called by muse, mutect2, varscan2
- TLL1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1452918005, COSV50269380; called by muse, mutect2, varscan2
- UBE2W | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62473881; called by muse, mutect2, varscan2
- USP45 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV57328284; called by muse, mutect2, varscan2
- VARS1 | c.2242-1G>A p.X748_splice | Splice Site (SNP) | VAF 7/147 reads (5%) | catalogued as COSV63304384; called by muse, mutect2
- ZBED9 | c.3838G>A p.G1280R | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.635); catalogued as rs140560647; called by muse, mutect2, varscan2
- ZCCHC12 | c.53T>G p.L18W | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59571245, COSV59572380; called by muse, mutect2, varscan2
- ZNF445 | c.2830C>G p.L944V | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV68538671; called by muse, mutect2, varscan2
- ZNF676 | c.457G>A p.V153I (on ENST00000650058; = p.V121I on NM_001001411.3) | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as rs376158454; called by muse, mutect2, varscan2
- ZNF780B | c.1041G>C p.K347N | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.601); catalogued as COSV55463014; called by muse, mutect2, varscan2
- ZNF862 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 37/164 reads (23%) | catalogued as COSV56223397, COSV56226467; called by muse, mutect2, varscan2
- HNF1B | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOOK3 | c.1465dup p.I489Nfs*10 | Frame Shift Ins (INS) | VAF 53/167 reads (32%) | called by mutect2, pindel, varscan2
- TOP3A | c.349_350del p.E117Nfs*2 | Frame Shift Del (DEL) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- ADAM28 | c.1734G>T p.R578= | Silent (SNP) | VAF 78/216 reads (36%) | catalogued as COSV56099201, COSV56105796; called by muse, mutect2, varscan2
- ASXL1 | c.1830C>T p.G610= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs199829982; called by muse, mutect2, varscan2
- CD163 | c.2076G>A p.S692= | Silent (SNP) | VAF 44/147 reads (30%) | catalogued as rs374794909; called by muse, mutect2, varscan2
- CKAP5 | c.2997G>A p.L999= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV56363411; called by muse, mutect2, varscan2
- CNN2 | c.375C>T p.L125= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs775599276, COSV54045954; called by muse, mutect2, varscan2
- DENND1A | c.1176C>T p.G392= | Silent (SNP) | VAF 102/293 reads (35%) | catalogued as rs747557895, COSV65324124; called by muse, mutect2, varscan2
- DNAH1 | c.8019C>T p.D2673= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs759999285, COSV70227608; called by muse, mutect2, varscan2
- DNAH11 | c.3333G>A p.V1111= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as rs1469670866, COSV60948653; called by muse, mutect2, varscan2
- KIRREL2 | c.864C>T p.P288= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV52875194; called by muse, mutect2, varscan2
- KRTAP10-10 | c.162G>A p.Q54= | Silent (SNP) | VAF 61/119 reads (51%) | catalogued as COSV59956827; called by muse, mutect2, varscan2
- PPARGC1B | c.939C>T p.P313= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as rs747264689, COSV100495022, COSV58528003; called by muse, mutect2, varscan2
- PRDM9 | c.939C>A p.A313= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV57004468; called by muse, mutect2, varscan2
- SETBP1 | c.4362C>T p.R1454= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1568058620, COSV56317422; called by muse, mutect2, varscan2
- SLC9A3 | c.369C>T p.I123= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs144657077; called by muse, mutect2
- ST8SIA3 | c.573C>T p.F191= | Silent (SNP) | VAF 57/194 reads (29%) | catalogued as rs376754702; called by muse, mutect2, varscan2
- SYT16 | c.1518G>A p.A506= | Silent (SNP) | VAF 50/148 reads (34%) | catalogued as rs200581957, COSV70854823; called by muse, mutect2, varscan2
- TRPC7 | c.240C>T p.N80= | Silent (SNP) | VAF 48/162 reads (30%) | catalogued as rs372900766, COSV61456123; called by muse, mutect2, varscan2
- TTN | c.47082C>T p.R15694= (on ENST00000591111; = p.R8270= on NM_003319.4) | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs940135679, COSV59965340; called by muse, mutect2, varscan2
